Somatic mutation profile of tumor specimen TARGET-20-PATALD-09A (aliquot TARGET-20-PATALD-09A-01D) from TARGET case TARGET-20-PATALD, project TARGET-AML (Acute Myeloid Leukemia). Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow.
Specimen TARGET-20-PATALD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d45e083b-7fbd-4c37-bd4e-d9f61d226a70.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATALD-14A (Bone Marrow Normal), aliquot TARGET-20-PATALD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c3aaf58-c7eb-4259-a58b-31c218f5cd3f

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 64/156 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ASXL2 | c.1185_1186dup p.P396Lfs*7 | Frame Shift Ins (INS) | VAF 69/221 reads (31%) | called by mutect2, pindel, varscan2
- STAG1 | c.857A>T p.N286I | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
